Somatic mutation profile of tumor specimen 0DHBCZ from CCDI case PBBTNG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Age at diagnosis: 10.2 years (3,720 days).
Specimen 0DHBCZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98bc531e-6de2-4458-8863-9b2c99f8ce2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHBCW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31939704-6113-4673-889b-f879e67dd67e

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, 5'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NCKAP5L | c.634T>C p.W212R | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1297883221; called by muse, mutect2, varscan2
- POM121 | c.1024C>T p.R342C (on ENST00000434423; = p.R77C on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/666 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs149716008; called by muse, mutect2, varscan2
- SH3GL3 | c.992C>A p.S331* | Nonsense Mutation (SNP) | VAF 68/528 reads (13%) | catalogued as COSV100195720; called by muse, mutect2
- EPHA1 | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 44/616 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.199); called by muse, mutect2
- NEUROD6 | c.300C>T p.N100= | Silent (SNP) | VAF 98/648 reads (15%) | catalogued as rs374292030, COSV99774060; called by muse, varscan2
- NUP214 | c.6018G>A p.S2006= | Silent (SNP) | VAF 52/703 reads (7%) | catalogued as COSV63913048; called by muse, mutect2
- SAMD9 | c.3423C>T p.N1141= | Silent (SNP) | VAF 84/568 reads (15%) | catalogued as rs771055414, COSV66074688; called by muse, mutect2, varscan2
- EN1 | c.-94G>T | 5'UTR (SNP) | VAF 8/147 reads (5%) | called by muse, mutect2
- NSD3 | c.2612-45G>A | Intron (SNP) | VAF 12/107 reads (11%) | called by mutect2, varscan2
